Gene-level copy-number profile of tumor specimen TCGA-A5-A0GI-01A from TCGA case TCGA-A5-A0GI, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G2; Age at diagnosis: 63.5 years (23,195 days).
Specimen TCGA-A5-A0GI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.a891df8a-bfe4-4327-8472-be99146e8934.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,193 have no estimate.
https://portal.gdc.cancer.gov/files/e6a2895f-d79f-4a1f-b6e4-9b7ae76aff0f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 2: 52,861; copy number 3: 2,569.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A5-A0GI-01A-11D-A042-01): tumor purity 0.96, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
